Somatic mutation profile of tumor specimen TCGA-YL-A8SP-01B (aliquot TCGA-YL-A8SP-01B-11D-A377-08) from TCGA case TCGA-YL-A8SP, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.7 years (21,455 days).
Specimen TCGA-YL-A8SP-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d5f1b55-3392-466d-984a-eec1eca331df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A8SP-10A (Blood Derived Normal), aliquot TCGA-YL-A8SP-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92c5baaf-28b2-4139-9ea6-0968c1838930

The open-access MAF lists 27 somatic variants for this specimen: 16 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 10, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG1 | c.959A>G p.N320S | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV100494514; called by muse, mutect2, varscan2
- ABRA | c.328T>C p.S110P | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100357658; called by muse, mutect2
- ADAM29 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs555477715, COSV63664187; called by muse, mutect2, varscan2
- EGFR | c.2989T>G p.F997V | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV51810684; called by muse, mutect2, varscan2
- GREM2 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV100547720; called by muse, mutect2, varscan2
- LTF | c.732C>A p.D244E | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs141357150, COSV99211663; called by muse, mutect2, varscan2
- MUC17 | c.13444C>T p.R4482* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as rs148704443; called by mutect2, varscan2
- NUP85 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs545929051, COSV99822345; called by muse, mutect2
- PCDH11Y | c.1576G>A p.D526N (on ENST00000400457 / NM_032973.2; = p.D515N on NM_032971.3) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99292684; called by muse, mutect2, varscan2
- PDZD2 | c.2460G>T p.E820D | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV99226677; called by muse, mutect2, varscan2
- POTEF | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.29); catalogued as rs759505981, COSV100665338; called by muse, mutect2, varscan2
- SERINC3 | c.134T>G p.I45S | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99667988; called by muse, mutect2, varscan2
- SORCS1 | c.1107C>A p.D369E | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV99550271; called by muse, mutect2, varscan2
- SRSF12 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as COSV101504996; called by muse, mutect2, varscan2
- TLE1 | c.1753G>A p.D585N | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1467487618, COSV64722198; called by muse, mutect2, varscan2
- ZNF676 | c.1310C>T p.S437F (on ENST00000650058; = p.S405F on NM_001001411.3) | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.101); catalogued as COSV101236347, COSV68094010; called by muse, mutect2, varscan2
- ANKRD35 | c.879G>A p.P293= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs782512163, COSV100841854; called by muse, mutect2, varscan2
- DST | c.651C>T p.Y217= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs377724610, COSV104396082; called by muse, mutect2, varscan2
- KDM4B | c.192C>T p.D64= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as rs753456068, COSV50272981; called by muse, mutect2, varscan2
- KDM5D | c.1467G>T p.V489= | Silent (SNP) | VAF 26/32 reads (81%) | catalogued as COSV100522314; called by muse, mutect2, varscan2
- MEDAG | c.831A>T p.S277= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV66850766; called by muse, mutect2, varscan2
- MRGPRX1 | c.435G>C p.L145= | Silent (SNP) | VAF 29/54 reads (54%) | catalogued as COSV100246157; called by muse, mutect2, varscan2
- MXRA5 | c.5028G>A p.L1676= | Silent (SNP) | VAF 17/182 reads (9%) | catalogued as COSV54251840, COSV99479203; called by muse, mutect2
- OR6C3 | c.348C>T p.S116= | Silent (SNP) | VAF 53/129 reads (41%) | catalogued as COSV101110389; called by muse, mutect2, varscan2
- TGFB1 | c.969C>T p.L323= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs776406237, COSV55727012; called by mutect2, varscan2
- TRIOBP | c.3405A>G p.L1135= | Silent (SNP) | VAF 43/96 reads (45%) | catalogued as COSV60384628; called by muse, mutect2, varscan2
- DCHS2 | n.2175C>A | RNA (SNP) | VAF 37/75 reads (49%) | catalogued as COSV100253157; called by muse, mutect2, varscan2
